Gene-level copy-number profile of tumor specimen TCGA-12-0820-01A from TCGA case TCGA-12-0820, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.7 years (14,878 days).
Specimen TCGA-12-0820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.1f02a490-07c9-40d5-b261-755c4ac756c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0820-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/629909df-5a23-4b59-884d-9c3a25af0ae9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 6,253; copy number 2: 47,220; copy number 3: 6,239; copy number 4: 16; copy number 19: 9; copy number 21: 11; copy number 25: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0820-01A-01D-0384-01): tumor purity 0.88, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–8,344,167, 24 genes: AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr10:87,817,928–89,207,317, 33 genes: CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–277,123, 11 genes, copy number 21: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4.
- chr12:3,871,579–4,445,614, 11 genes, copy number 25 (within-gene range 2–25): PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6.
- chr12:21,827,210–21,887,957, 1 gene, copy number 25 (within-gene range 2–25): AC008250.1.
- chr12:57,723,761–57,782,541, 9 genes, copy number 19: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3.

Autosomal genes at a single copy (total copy number 1): 3,873. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
